Somatic mutation profile of tumor specimen TCGA-FY-A3I4-01A (aliquot TCGA-FY-A3I4-01A-11D-A21A-08) from TCGA case TCGA-FY-A3I4, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 34.7 years (12,677 days).
Specimen TCGA-FY-A3I4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a6385c6-bc29-403a-b336-ec48c78babfc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FY-A3I4-10A (Blood Derived Normal), aliquot TCGA-FY-A3I4-10A-01D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/48bedf32-6078-4528-8204-be9c8cdb5c42

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- NUP214 | c.4049A>G p.N1350S | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV63909796; called by muse, mutect2, varscan2
- ZNF578 | c.997C>G p.H333D | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV69736540, COSV69736542; called by muse, varscan2
- CASC3 | c.486G>A p.V162= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV52867572; called by muse, mutect2, varscan2
- SMARCA1 | c.534G>C p.V178= | Silent (SNP) | VAF 17/90 reads (19%) | catalogued as COSV64412056; called by muse, mutect2, varscan2
